Somatic mutation profile of tumor specimen 0DUB84 from CCDI case PBCGYE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.9 years (3,989 days).
Specimen 0DUB84: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 938bd541-0c94-4b69-87ab-7eb039b0c8ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUB63 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/25de5810-0388-4f56-90a4-958460b750d2

The open-access MAF lists 24 somatic variants for this specimen: 14 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 6, Intron 3, Splice Region 2, Nonsense Mutation 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH10 | c.8020C>T p.H2674Y (on ENST00000409039; = p.H2613Y on NM_207437.3) | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.657); catalogued as COSV68998908; called by muse, varscan2
- GPR162 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 40/183 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs782148352; called by muse, varscan2
- MKLN1 | c.1321C>A p.L441I | Missense Mutation (SNP) | VAF 64/380 reads (17%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.541); catalogued as COSV61760547; called by muse, varscan2
- NDUFA3 | c.11-2A>G p.X4_splice | Splice Site (SNP) | VAF 15/95 reads (16%) | catalogued as rs113966269; called by muse, varscan2
- NEB | c.18918G>A p.S6306= | Splice Region (SNP) | VAF 41/186 reads (22%) | catalogued as rs1230102324, COSV51430461; called by muse, varscan2
- NEB | c.11921G>A p.R3974H | Missense Mutation (SNP) | VAF 26/179 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as rs373850451; called by muse, varscan2
- PROM2 | c.1729T>C p.Y577H | Missense Mutation (SNP) | VAF 36/188 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs752335624; called by muse, varscan2
- SLC25A20 | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs200418177, COSV100033529, COSV100033744; called by muse, varscan2
- SLC26A8 | c.1702T>C p.Y568H | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV62887855; called by muse, varscan2
- AHNAK2 | c.13571C>A p.A4524D | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); called by muse, varscan2
- GABRB1 | c.613A>T p.K205* | Nonsense Mutation (SNP) | VAF 40/237 reads (17%) | called by muse, varscan2
- KDR | c.691T>C p.S231P | Missense Mutation (SNP) | VAF 44/248 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, varscan2
- TAS1R2 | c.486C>A p.I162= | Splice Region (SNP) | VAF 44/206 reads (21%) | called by muse, varscan2
- TMC5 | c.1427T>A p.F476Y (on ENST00000396229 / NM_001105248.1; = p.F230Y on NM_024780.5) | Missense Mutation (SNP) | VAF 46/186 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.424); called by muse, varscan2
- DNAJC9 | c.744A>T p.G248= | Silent (SNP) | VAF 38/248 reads (15%) | catalogued as rs781218421; called by muse, varscan2
- FAT1 | c.72C>T p.S24= | Silent (SNP) | VAF 107/306 reads (35%) | called by muse, varscan2
- ITPR3 | c.1164G>A p.R388= | Silent (SNP) | VAF 34/214 reads (16%) | called by muse, varscan2
- KSR2 | c.1812A>G p.G604= | Silent (SNP) | VAF 68/352 reads (19%) | called by muse, varscan2
- PTPRD | c.54G>C p.T18= | Silent (SNP) | VAF 34/234 reads (15%) | catalogued as COSV100642394; called by muse, varscan2
- SIM1 | c.1989G>A p.S663= | Silent (SNP) | VAF 22/184 reads (12%) | catalogued as rs151274826; ClinVar: likely benign; called by muse, varscan2
- ABCC12 | c.*11G>A | 3'UTR (SNP) | VAF 76/206 reads (37%) | catalogued as rs371058499; called by muse, varscan2
- ADAMTSL4 | c.2383-84G>C | Intron (SNP) | VAF 18/52 reads (35%) | called by muse, varscan2
- HDAC6 | c.1791+26G>A | Intron (SNP) | VAF 13/60 reads (22%) | called by muse, varscan2
- LMBR1 | c.994-33C>G | Intron (SNP) | VAF 24/196 reads (12%) | called by muse, varscan2
